CCDI case PBBIMX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ee595c42-0086-4cb0-bd47-7f01d74eb1bd

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, benign: ICD-O-3 morphology code: 8000/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.5 years (542 days).

Biospecimens (3 samples)
- Sample 0D9QL7: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D9QL8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0D9QL9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
